Gene-level copy-number profile of tumor specimen ALCH-AE78-TTP1-A from ALCHEMIST case ALCH-AE78, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.5 years (21,001 days).
Specimen ALCH-AE78-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d5637be-49dd-46d7-a3ff-936a01a20830.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE78-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/f85d9c5a-f48e-4d9c-87e7-7ff0843069fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 2,730; copy number 2: 31,103; copy number 3: 14,235; copy number 4: 7,685; copy number 5: 1,124; copy number 6: 971; copy number 7: 241; copy number 8: 94; copy number 9: 32; copy number 10: 12; copy number 11: 77; copy number 14: 8; copy number 16: 2; copy number 21: 32.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:923,928–959,309, 2 genes: SAMD11, NOC2L.
- chr2:241,881,363–242,084,233, 7 genes (within-gene range 0–2): LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:29,887,294–29,906,909, 4 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1.
- chr6:29,925,983–29,945,884, 5 genes: HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1.
- chr9:61,581,813–61,627,683, 2 genes: AL935212.3, FAM242D.
- chr9:64,488,600–64,489,786, 1 gene: GXYLT1P6.
- chr9:64,637,845–64,811,429, 5 genes: AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4.
- chr17:20,449,395–20,494,155, 4 genes: LGALS9B, TNPO1P3, YWHAEP3, KRT16P5.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr22:31,064,105–31,140,508, 6 genes (within-gene range 0–2): SMTN, AC005005.3, SELENOM, AC005005.2, INPP5J, PLA2G3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,593 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:54,456,317–54,671,446, 4 genes, copy number 5 (within-gene range 2–5): SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1.
- chr2:59,217,708–65,432,637, 139 genes, copy number 5–21 (within-gene range 2–21) (broad region; genes not listed).
- chr2:97,756,333–98,356,005, 6 genes, copy number 6 (within-gene range 4–6): TMEM131, HMGN1P36, RNU7-96P, VWA3B, ATP5F1BP1, AC092675.1.
- chr2:98,346,995–98,351,140, 1 gene, copy number 6 (within-gene range 4–6): AC092675.2.
- chr2:109,542,799–109,618,990, 4 genes, copy number 5: SEPTIN10, RPL37P12, AC011753.2, SOWAHC.
- chr2:113,970,719–126,702,942, 113 genes, copy number 5 (broad region; genes not listed).
- chr2:169,479,480–184,382,869, 262 genes, copy number 6–7 (broad region; genes not listed).
- chr3:141,228,726–141,367,753, 1 gene, copy number 5 (within-gene range 3–5): PXYLP1.
- chr3:141,267,353–198,123,232, 973 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:58,198–1,851,497, 65 genes, copy number 5–6 (broad region; genes not listed).
- chr5:12,297,399–14,699,850, 20 genes, copy number 5: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, TRIO, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1, OTULIN.
- chr5:27,217,714–29,516,504, 19 genes, copy number 5: PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1.
- chr5:34,373,028–34,958,964, 11 genes, copy number 5: AC138853.1, AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21.
- chr5:43,571,594–43,707,405, 5 genes, copy number 6: NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12.
- chr5:51,372,736–53,881,051, 31 genes, copy number 7–9: AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1.
- chr5:54,643,557–55,233,608, 20 genes, copy number 6: AC016583.1, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO.
- chr6:40,391,591–40,587,364, 1 gene, copy number 7 (within-gene range 3–7): LRFN2.
- chr6:40,501,631–46,761,158, 172 genes, copy number 7–11 (broad region; genes not listed).
- chr7:79,768,028–80,226,181, 1 gene, copy number 5 (within-gene range 4–5): GNAI1.
- chr7:80,096,600–85,636,344, 43 genes, copy number 5: RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1, AC004866.1, AC004866.2, EIF4EP4, AC008163.1, DDX43P3, HGF, CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr7:99,558,406–107,564,261, 238 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:107,470,018–107,475,684, 1 gene, copy number 6 (within-gene range 2–6): GPR22.
- chr8:43,672,823–43,674,591, 2 genes, copy number 7: AC139365.2, AC139365.1.
- chr8:58,411,359–71,228,629, 183 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:86,333,274–86,343,429, 1 gene, copy number 5 (within-gene range 2–5): AC103760.1.
- chr8:86,468,257–88,887,573, 24 genes, copy number 5 (within-gene range 2–5): RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2.
- chr9:63,581,254–63,859,641, 13 genes, copy number 5: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP.
- chr12:37,575,587–38,329,721, 12 genes, copy number 5: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:55,608,043–55,684,611, 7 genes, copy number 5 (within-gene range 3–5): OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B.
- chr12:66,950,754–67,319,953, 5 genes, copy number 6: AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1.
- chr12:107,093,298–107,123,314, 1 gene, copy number 5 (within-gene range 2–5): AC078929.1.
- chr14:44,444,747–46,651,781, 29 genes, copy number 5: LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr16:21,587,627–22,612,196, 37 genes, copy number 5: AC005632.1, METTL9, AC005632.3, IGSF6, RNU6-1005P, RNU6-196P, OTOA, AC092375.2, RRN3P1, AC092375.3, NPIPB4, SMG1P4, AC092375.1, AC092119.2, UQCRC2, PDZD9, AC092119.1, AC092119.3, MOSMO, AC009019.1, VWA3A, SDR42E2, AC009019.2, EEF2K, AC009034.1, POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B, RRN3P3, SMG1P1, NPIPB5, AC106788.1, OTOAP1, AC009021.2.
- chr16:32,715,931–32,824,645, 10 genes, copy number 5–14: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10, AC137761.1, AC137761.2.
- chr16:32,877,469–32,888,874, 2 genes, copy number 16: SLC6A10P, AC142086.1.
- chr17:37,798,894–39,877,896, 87 genes, copy number 5 (broad region; genes not listed).
- chr20:30,278,906–31,870,747, 46 genes, copy number 5 (within-gene range 4–5): LINC01597, AL121762.1, AL121762.2, Y_RNA, FAM242A, FRG1BP, MLLT10P1, 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528, DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15.
- chr21:43,053,191–43,107,570, 2 genes, copy number 5–11: CBS, U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 7–11: MRPL51P2, FRGCA.

Autosomal genes at a single copy (total copy number 1): 2,256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
